FM case AD1381 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/c94f7c1c-e3f7-45d0-aaef-0ef8c3438677

Female, 67.1 years: Serous carcinoma, NOS (ICD-O-3 8441/3) of the ovary; primary biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
